Somatic mutation profile of tumor specimen ALCH-B2UV-TTP1-A (aliquot ALCH-B2UV-TTP1-A-1-0-D-A77K-36) from ALCHEMIST case ALCH-B2UV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.1 years (21,226 days).
Specimen ALCH-B2UV-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3dd1fc97-0d44-4952-89b6-5abd9f206b85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2UV-NB1-A (Blood Derived Normal), aliquot ALCH-B2UV-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0a36164-f87c-44bc-a07a-c3cf1865a385

The open-access MAF lists 53 somatic variants for this specimen: 29 protein-altering or splice-affecting, 13 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 13, Nonsense Mutation 6, Intron 4, 5'UTR 3, RNA 2, 5'Flank 1, Splice Region 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 17/155 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- ADAMTS12 | c.205T>A p.Y69N | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as rs768908976; called by muse, mutect2, varscan2
- ATP8B3 | c.757A>G p.M253V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs900839178; called by muse, varscan2
- CAND1 | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 20/371 reads (5%) | catalogued as COSV73389756; called by muse, mutect2
- GPATCH4 | c.349-1G>C p.X117_splice | Splice Site (SNP) | VAF 10/182 reads (5%) | catalogued as COSV58039848, COSV58040573; called by muse, mutect2
- HSD17B3 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV64556183; called by muse, mutect2
- NLGN4X | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs199525017, COSV52022976, COSV52026711; ClinVar: uncertain significance; called by muse, mutect2
- PRPF3 | c.1527-5G>T | Splice Region (SNP) | VAF 70/346 reads (20%) | catalogued as rs782779487, COSV61394687; called by muse, mutect2, varscan2
- SLC8B1 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as COSV99176648; called by muse, mutect2, varscan2
- USP40 | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 7/109 reads (6%) | catalogued as rs1194907738; called by muse, mutect2
- VRK2 | c.1349G>A p.W450* | Nonsense Mutation (SNP) | VAF 18/435 reads (4%) | catalogued as COSV99287697; called by muse, mutect2
- ZNF44 | c.1277C>G p.S426* (on ENST00000356109 / NM_001164276.2; = p.S378* on NM_016264.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 5/91 reads (5%) | catalogued as COSV100633568; called by muse, mutect2
- BTN2A1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- C3orf70 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- DCAF12 | c.130A>G p.R44G | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2
- DRD2 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2
- EBLN1 | c.585G>A p.W195* | Nonsense Mutation (SNP) | VAF 9/305 reads (3%) | called by muse, mutect2
- ELOA | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.015); called by muse, mutect2
- FOCAD | c.5087G>C p.S1696T | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2
- FREM2 | c.8648A>G p.E2883G | Missense Mutation (SNP) | VAF 24/784 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- GMCL1 | c.1355T>C p.I452T | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2
- GOLGA4 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OLFML2B | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- POLR3G | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 9/235 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBM6 | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 14/271 reads (5%) | called by muse, mutect2
- SACS | c.2798C>G p.S933C | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- SSH2 | c.937G>C p.E313Q | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.313); called by muse, mutect2
- TIMM23 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 51/399 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZC3HC1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.524); called by muse, mutect2
- ACVR1B | c.426C>T p.I142= | Silent (SNP) | VAF 12/385 reads (3%) | called by muse, mutect2
- ADGRB2 | c.3639G>A p.V1213= | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- CPNE3 | c.267G>A p.L89= | Silent (SNP) | VAF 12/212 reads (6%) | called by muse, mutect2
- GLB1 | c.231G>A p.L77= | Silent (SNP) | VAF 10/239 reads (4%) | called by muse, mutect2
- LOX | c.831C>T p.F277= | Silent (SNP) | VAF 10/291 reads (3%) | catalogued as COSV99140593; called by muse, mutect2
- MVP | c.2286C>T p.V762= | Silent (SNP) | VAF 7/128 reads (5%) | called by muse, mutect2
- NCR3LG1 | c.168C>G p.L56= | Silent (SNP) | VAF 8/228 reads (4%) | called by muse, mutect2
- RPS6KA3 | c.1704G>C p.L568= | Silent (SNP) | VAF 16/594 reads (3%) | catalogued as COSV65386691; called by muse, mutect2
- TFDP3 | c.369G>A p.Q123= | Silent (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- TSPAN15 | c.672C>T p.I224= | Silent (SNP) | VAF 10/62 reads (16%) | called by muse, varscan2
- TSPAN15 | c.724C>T p.L242= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, varscan2
- USP51 | c.1800G>A p.E600= | Silent (SNP) | VAF 7/154 reads (5%) | called by muse, mutect2
- ZNF180 | c.1890G>A p.E630= | Silent (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- AL353622.2 | chr1:28246658 C>T | 5'Flank (SNP) | VAF 15/339 reads (4%) | called by muse, mutect2
- ATM | c.7307+47G>A | Intron (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2
- ATP8B3 | c.904+98C>T | Intron (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- CCDC121 | c.-119+337C>T | Intron (SNP) | VAF 24/188 reads (13%) | called by muse, mutect2, varscan2
- DNMT1 | c.4816+45C>T | Intron (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2
- FBRS | c.-125G>T | 5'UTR (SNP) | VAF 3/24 reads (13%) | called by muse, varscan2
- ISL1 | c.-9C>T | 5'UTR (SNP) | VAF 19/410 reads (5%) | catalogued as rs982868662; called by muse, mutect2
- NACA4P | n.777G>A | RNA (SNP) | VAF 20/408 reads (5%) | called by muse, mutect2
- SNHG10 | chr14:95517178 C>T | 3'Flank (SNP) | VAF 4/42 reads (10%) | catalogued as rs1390267240; called by muse, mutect2
- SNX14 | c.-13C>T | 5'UTR (SNP) | VAF 7/152 reads (5%) | catalogued as COSV59013274; called by muse, mutect2
- SSX9P | n.347G>A | RNA (SNP) | VAF 13/322 reads (4%) | called by muse, mutect2
